MMRF case MMRF_1717 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/77da093f-cf72-4643-ad5b-b6f6b18d227b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.5 years (23,560 days); ISS stage: II; Days to last known disease status: 1,092 days (3.0 years); Days to last follow up: 1,092 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 160 days; Days to treatment end: 162 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 334 days; Days to treatment end: 391 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 419 days (1.1 years); Days to treatment end: 454 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 454 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 1): M Protein 4.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.315 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 67.8 mg/dL; Immunoglobulin G 71.5 g/L; Immunoglobulin A 0.152 g/L; Immunoglobulin M 0.089 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 12.3 ×10⁹/L; Absolute Neutrophil 7.75 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 22 g/L; Total Protein 9.7 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 4.68 mg/dL.
- Day 89 (ECOG 1): M Protein 0.442 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 9.02 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.67 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 9.3 mmol/L.
- Day 123 (ECOG 1): M Protein 0.476 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.329 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 8.68 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 274 (ECOG 1): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.873 mg/dL; Immunoglobulin G 9.6 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 9.67 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.17 mmol/L.
- Day 363 (ECOG 1): M Protein 0.357 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.588 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 8.27 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.44 mmol/L.
- Day 454 (ECOG 1): M Protein 0.296 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.645 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 9.11 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 796 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 7.21 mmol/L.
- Day 531 (ECOG 1): M Protein 0.241 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 9.2 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 629 (ECOG 1): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 9.56 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 9.55 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 6.16 mmol/L.
- Day 720 (ECOG 1): M Protein 0.168 g/dL; Immunoglobulin G 9.35 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 9.49 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.82 mmol/L.
- Day 811 (ECOG 1): M Protein 0.185 g/dL; Immunoglobulin G 9.94 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 10.3 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.26 mmol/L.
- Day 895 (ECOG 1): M Protein 0.13 g/dL; Immunoglobulin G 9.77 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 9.8 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 7.26 mmol/L.
- Day 1,000 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 10.1 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 7.65 mmol/L.
- Day 1,092 (ECOG 1): M Protein 0.104 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 9.92 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 7.37 mmol/L.

Other clinical attributes
- Day -16: Weight: 101 kg; Height: 185 cm.

Biospecimens (2 samples)
- Sample MMRF_1717_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1717_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
